Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-5686, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-5686-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY AND ADRENAL GLAND, RADICAL NEPHRECTOMY:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN NUCLEAR GRADE 3.

TUMOR MEASURES 6.5 CM IN MAXIMUM DIMENSION.

TUMOR IS CONFINED TO THE KIDNEY.

Margins of resection, negative for tumor.

Adrenal gland, no tumor present.

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL GLAND - A radical nephrectomy specimen (15.2 x 14.1 x 6.2 cm) including the left kidney (12.2 x 6.1 x 6.0 cm), a segment of renal artery, the renal vein, and ureter (9.0 cm in length by 0.8 cm average diameter), and the adrenal gland (4.0 x 3.2 x 1.2 cm).

There is a 6.5 x 6.0 x 5.2 cm, well-circumscribed tumor in the upper pole of the kidney. The tumor is yellow-tan, with extensive areas of hemorrhage and necrosis. The tumor is confined to the kidney, although it does abut the capsule. The tumor does not invade into the perinephric adipose tissue, renal sinus, or renal vein. The tumor comes to within 0.3 cm of the renal sinus and renal calyces. The tumor does not extend to Gerota's fascia.

The adjacent kidney parenchyma is unremarkable. The pelvicalyceal system is smooth, devoid of any lesions. No lymph nodes are identified in the hilar area. Cross sections of the right adrenal gland show unremarkable cortex and medulla.

Portions of the tumor are submitted for possible electron microscopy, as well as other research protocols.

Tissue has been submitted to tissue bank.

INK CODE: Green - Gerota's fascia.

SECTION CODE: A1, ureter, renal vein margin; A2, A3, tumor abutting ink (stain); A4, A5, tumor in relationship to pelvis/sinus; A6, A7, tumor in relationship to normal renal parenchyma; A8, sections of pale yellow tan tumor foci; A9, section of normal renal parenchyma; A10, section of unremarkable adrenal gland. [REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-82123

Source: NCI Genomic Data Commons file 387d5423-374d-4224-a4f4-32ba20ef4836 (TCGA-CJ-5686.1C2CB105-9894-40A2-A22D-EB2111AE0507.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).